Somatic mutation profile of tumor specimen ALCH-B1YF-TTP1-A (aliquot ALCH-B1YF-TTP1-A-3-0-D-A772-36) from ALCHEMIST case ALCH-B1YF, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 65.1 years (23,786 days).
Specimen ALCH-B1YF-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) cc11f0b3-1574-4960-80c6-a4548a16b7fe.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B1YF-NB1-A (Blood Derived Normal), aliquot ALCH-B1YF-NB1-A-1-0-D-A772-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c7922ae3-c8b1-45b9-bccf-5e9556f358c6

The open-access MAF lists 117 somatic variants for this specimen: 84 protein-altering or splice-affecting, 21 silent, 12 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 71, Silent 21, Intron 9, Nonsense Mutation 7, Frame Shift Del 3, Splice Site 2, 5'UTR 2, 3'UTR 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.34G>T p.G12C | Missense Mutation (SNP) | VAF 96/320 reads (30%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as rs121913530, CM076251, COSV55497461, COSV55497469, COSV55497582, COSV56157736; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- TP53 | c.653T>A p.V218E | Missense Mutation (SNP) | VAF 17/137 reads (12%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV52690974, COSV52712839, COSV52761003; called by muse, mutect2, varscan2
- BANK1 | c.119G>T p.W40L | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59844662; called by muse, mutect2
- CACNA1S | c.259-1G>T p.X87_splice | Splice Site (SNP) | VAF 12/166 reads (7%) | catalogued as COSV62944933; called by muse, mutect2
- CBX8 | c.215G>A p.R72H | Missense Mutation (SNP) | VAF 12/110 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV53935593; called by muse, mutect2
- CIT | c.1030G>A p.G344S | Missense Mutation (SNP) | VAF 18/243 reads (7%) | SIFT tolerated (0.22); PolyPhen benign (0.031); catalogued as rs369209873, COSV55881092; called by muse, mutect2
- CPNE4 | c.1047C>A p.C349* | Nonsense Mutation (SNP) | VAF 24/354 reads (7%) | catalogued as COSV70198380; called by muse, mutect2
- DCAF4L2 | c.273A>T p.Q91H | Missense Mutation (SNP) | VAF 10/139 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.141); catalogued as COSV100151192; called by muse, mutect2
- DICER1 | c.3359A>G p.N1120S | Missense Mutation (SNP) | VAF 7/204 reads (3%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as rs1555369701, COSV58624940; ClinVar: uncertain significance; called by muse, mutect2
- DNAH10 | c.11389G>A p.E3797K (on ENST00000409039; = p.E3736K on NM_207437.3) | Missense Mutation (SNP) | VAF 11/102 reads (11%) | SIFT tolerated (0.28); PolyPhen benign (0.125); catalogued as rs1214736953; called by muse, mutect2, varscan2
- FRAS1 | c.5822G>A p.R1941H | Missense Mutation (SNP) | VAF 14/122 reads (11%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.773); catalogued as rs771945455; called by muse, mutect2, varscan2
- FSIP2 | c.8958C>A p.N2986K | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT tolerated (0.21); PolyPhen benign (0.011); catalogued as COSV58077483; called by muse, varscan2
- GABRA2 | c.1019G>C p.R340T | Missense Mutation (SNP) | VAF 24/306 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV62917407; called by muse, mutect2
- GLI2 | c.2593A>T p.T865S (on ENST00000361492 / NM_001374353.1; = p.T882S on NM_005270.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/57 reads (11%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.879); catalogued as rs1332140763; ClinVar: uncertain significance; called by muse, mutect2
- IL12RB1 | c.175C>T p.R59C | Missense Mutation (SNP) | VAF 25/165 reads (15%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as rs865858530, COSV59096650; called by muse, mutect2, varscan2
- ISOC1 | c.140A>G p.Y47C | Missense Mutation (SNP) | VAF 6/140 reads (4%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.157); catalogued as rs1323246175; called by muse, mutect2
- LRRTM4 | c.1240G>T p.E414* | Nonsense Mutation (SNP) | VAF 7/101 reads (7%) | catalogued as COSV69139072; called by muse, mutect2
- NCAPD3 | c.1794G>C p.Q598H | Missense Mutation (SNP) | VAF 12/174 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV101599380; called by muse, mutect2
- OR1M1 | c.476A>C p.H159P | Missense Mutation (SNP) | VAF 19/107 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); catalogued as rs748541045; called by muse, mutect2, varscan2
- OR2AK2 | c.818C>A p.A273E | Missense Mutation (SNP) | VAF 11/78 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.72); catalogued as COSV63549457; called by muse, varscan2
- PAPPA2 | c.278G>T p.G93V | Missense Mutation (SNP) | VAF 20/136 reads (15%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.329); catalogued as COSV62777606; called by muse, mutect2, varscan2
- PDZRN4 | c.2082C>A p.D694E (on ENST00000402685 / NM_001164595.2; = p.D436E on NM_013377.4) | Missense Mutation (SNP) | VAF 10/148 reads (7%) | SIFT tolerated (1); PolyPhen benign (0.035); catalogued as COSV54210334; called by muse, mutect2
- PRKAG3 | c.435G>T p.W145C | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as rs748763400, COSV52102608; called by mutect2, varscan2
- RGS1 | c.269T>C p.L90P | Missense Mutation (SNP) | VAF 25/186 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1357289806; called by muse, mutect2, varscan2
- RIF1 | c.1651C>T p.L551F | Missense Mutation (SNP) | VAF 11/163 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1466188708; called by muse, mutect2
- SEMA3C | c.514G>T p.V172L | Missense Mutation (SNP) | VAF 23/210 reads (11%) | SIFT tolerated (0.89); PolyPhen benign (0.006); catalogued as rs529243342, COSV54850790; called by muse, mutect2, varscan2
- TAS2R30 | c.298A>T p.T100S | Missense Mutation (SNP) | VAF 16/226 reads (7%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.652); catalogued as rs748299614; called by muse, mutect2
- ACACB | c.193C>T p.H65Y | Missense Mutation (SNP) | VAF 6/66 reads (9%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.011); called by muse, mutect2
- ANK2 | c.11422G>A p.E3808K | Missense Mutation (SNP) | VAF 20/258 reads (8%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.318); called by muse, mutect2
- ARGLU1 | c.529G>A p.E177K | Missense Mutation (SNP) | VAF 29/217 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- ARHGAP32 | c.4492C>T p.P1498S (on ENST00000310343 / NM_001378025.1; = p.P1149S on NM_014715.4) | Missense Mutation (SNP) | VAF 14/97 reads (14%) | SIFT tolerated, low confidence (0.49); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- BIN2 | c.355G>T p.D119Y | Missense Mutation (SNP) | VAF 9/105 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- BRINP2 | c.1701G>C p.M567I | Missense Mutation (SNP) | VAF 20/103 reads (19%) | SIFT tolerated (0.21); PolyPhen benign (0); called by muse, mutect2, varscan2
- CD200R1L | c.261G>T p.E87D | Missense Mutation (SNP) | VAF 35/286 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.078); called by muse, mutect2, varscan2
- CDC42BPA | c.2449T>A p.W817R | Missense Mutation (SNP) | VAF 40/319 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- CDC45 | c.240T>G p.N80K | Missense Mutation (SNP) | VAF 7/122 reads (6%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.951); called by muse, mutect2
- CFHR1 | c.836C>A p.A279E | Missense Mutation (SNP) | VAF 16/370 reads (4%) | SIFT tolerated (1); PolyPhen possibly damaging (0.531); called by muse, mutect2
- CLEC2B | c.391G>A p.A131T | Missense Mutation (SNP) | VAF 14/370 reads (4%) | SIFT tolerated (0.1); PolyPhen benign (0.014); called by muse, mutect2
- CPNE4 | c.1048C>A p.Q350K | Missense Mutation (SNP) | VAF 24/354 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2
- DDHD1 | c.1241T>G p.L414* (on ENST00000323669; = p.L611* on NM_030637.3) | Nonsense Mutation (SNP) | VAF 8/108 reads (7%) | called by muse, mutect2
- DST | c.4197+1G>C p.X1399_splice (on ENST00000361203 / NM_001374722.1; = p.X1073_splice on NM_001723.6) | Splice Site (SNP) | VAF 23/306 reads (8%) | called by muse, mutect2
- DTHD1 | c.1120C>T p.H374Y (on ENST00000456874; = p.H209Y on NM_001136536.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/262 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.22); called by muse, mutect2
- ECEL1 | c.832G>T p.A278S | Missense Mutation (SNP) | VAF 9/58 reads (16%) | SIFT tolerated (0.29); PolyPhen benign (0.387); called by muse, mutect2, varscan2
- FAM120A | c.76C>G p.L26V | Missense Mutation (SNP) | VAF 10/51 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); called by muse, varscan2
- FNDC8 | c.737T>C p.M246T | Missense Mutation (SNP) | VAF 18/220 reads (8%) | SIFT tolerated, low confidence (0.21); PolyPhen probably damaging (0.977); called by muse, mutect2
- GRIK5 | c.785C>A p.S262Y | Missense Mutation (SNP) | VAF 8/64 reads (13%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- HDGF | c.391G>T p.G131C | Missense Mutation (SNP) | VAF 33/289 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- HELZ2 | c.570+5G>A | Splice Region (SNP) | VAF 17/140 reads (12%) | called by muse, mutect2, varscan2
- HMCN2 | c.5194G>T p.V1732L | Missense Mutation (SNP) | VAF 27/98 reads (28%) | SIFT tolerated (0.39); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- ITGA2 | c.295A>T p.T99S | Missense Mutation (SNP) | VAF 32/314 reads (10%) | SIFT tolerated (0.74); PolyPhen benign (0.007); called by muse, mutect2
- KCND1 | c.1284G>C p.Q428H | Missense Mutation (SNP) | VAF 7/46 reads (15%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.615); called by muse, mutect2
- KDR | c.3194C>A p.A1065D | Missense Mutation (SNP) | VAF 26/265 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- KEAP1 | c.1116del p.L373Cfs*27 | Frame Shift Del (DEL) | VAF 4/20 reads (20%) | called by mutect2, pindel
- KLK9 | c.458G>T p.S153I | Missense Mutation (SNP) | VAF 2/24 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.744); called by muse, mutect2
- LAMA4 | c.3763G>A p.D1255N (on ENST00000230538 / NM_001105206.3; = p.D1248N on NM_002290.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/186 reads (4%) | SIFT tolerated (0.23); PolyPhen benign (0.02); called by muse, mutect2
- LRP2 | c.11593G>C p.D3865H | Missense Mutation (SNP) | VAF 10/320 reads (3%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.73); called by muse, mutect2
- MCPH1 | c.929T>A p.V310E | Missense Mutation (SNP) | VAF 10/141 reads (7%) | SIFT tolerated (0.15); PolyPhen benign (0.169); called by muse, mutect2
- MTCL1 | c.1729G>C p.E577Q (on ENST00000306329 / NM_001378206.1; = p.E217Q on NM_015210.4) | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- MYO1F | c.2789T>C p.M930T | Missense Mutation (SNP) | VAF 19/128 reads (15%) | SIFT tolerated (0.5); PolyPhen benign (0); called by muse, mutect2, varscan2
- MYPN | c.2921del p.P974Qfs*21 | Frame Shift Del (DEL) | VAF 20/173 reads (12%) | called by mutect2, varscan2
- NCR3LG1 | c.29G>T p.C10F | Missense Mutation (SNP) | VAF 5/31 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.088); called by muse, mutect2, varscan2
- NEXMIF | c.943G>T p.E315* | Nonsense Mutation (SNP) | VAF 10/189 reads (5%) | called by muse, mutect2
- NLRP14 | c.2420G>T p.C807F | Missense Mutation (SNP) | VAF 25/235 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- OR2G6 | c.434C>A p.A145D | Missense Mutation (SNP) | VAF 30/193 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- PCCA | c.1944A>C p.K648N | Missense Mutation (SNP) | VAF 25/232 reads (11%) | SIFT tolerated (0.09); PolyPhen benign (0.197); called by muse, mutect2, varscan2
- PDZRN4 | c.2083C>A p.Q695K (on ENST00000402685 / NM_001164595.2; = p.Q437K on NM_013377.4) | Missense Mutation (SNP) | VAF 10/146 reads (7%) | SIFT deleterious (0.05); PolyPhen benign (0.052); called by muse, mutect2
- PIEZO1 | c.2727del p.V911Wfs*91 | Frame Shift Del (DEL) | VAF 2/24 reads (8%) | called by pindel, varscan2
- PLOD3 | c.1114A>T p.R372W | Missense Mutation (SNP) | VAF 8/118 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- PTPN3 | c.1682T>G p.L561* | Nonsense Mutation (SNP) | VAF 10/112 reads (9%) | called by muse, mutect2
- RAB33A | c.595G>T p.A199S | Missense Mutation (SNP) | VAF 10/247 reads (4%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.77); called by muse, mutect2
- RAD54B | c.2570A>T p.H857L | Missense Mutation (SNP) | VAF 22/237 reads (9%) | SIFT tolerated (0.34); PolyPhen benign (0.015); called by muse, mutect2
- RAD54L | c.2075C>A p.P692Q | Missense Mutation (SNP) | VAF 17/178 reads (10%) | SIFT tolerated (0.11); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- RNF170 | c.244T>C p.Y82H | Missense Mutation (SNP) | VAF 25/297 reads (8%) | SIFT tolerated (0.44); PolyPhen benign (0.017); called by muse, mutect2
- SATL1 | c.716C>A p.P239Q (on ENST00000395409; = p.P426Q on NM_001012980.2) | Missense Mutation (SNP) | VAF 14/103 reads (14%) | SIFT tolerated (0.2); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- SIM1 | c.538T>A p.Y180N | Missense Mutation (SNP) | VAF 7/85 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); called by muse, mutect2
- SNX25 | c.1403C>A p.A468E | Missense Mutation (SNP) | VAF 15/95 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.322); called by muse, mutect2, varscan2
- SWAP70 | c.1165A>C p.T389P | Missense Mutation (SNP) | VAF 8/92 reads (9%) | SIFT tolerated (0.29); PolyPhen benign (0.091); called by muse, mutect2
- SYCP1 | c.2092G>T p.E698* | Nonsense Mutation (SNP) | VAF 14/152 reads (9%) | called by muse, mutect2, varscan2
- UNC79 | c.1043G>T p.R348M (on ENST00000393151 / NM_001346218.2; = p.R171M on NM_020818.5) | Missense Mutation (SNP) | VAF 16/211 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.929); called by muse, mutect2
- XIRP2 | c.5506G>C p.E1836Q (on ENST00000628543; = p.E2011Q on NM_152381.6) | Missense Mutation (SNP) | VAF 6/112 reads (5%) | SIFT tolerated (0.1); PolyPhen benign (0.074); called by muse, mutect2
- ZNF208 | c.715A>T p.S239C | Missense Mutation (SNP) | VAF 24/185 reads (13%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.899); called by muse, mutect2, varscan2
- ZNF33A | c.2212C>T p.H738Y (on ENST00000458705 / NM_006974.3; = p.H739Y on NM_006954.2) | Missense Mutation (SNP) | VAF 10/114 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); called by muse, mutect2
- ZNF649 | c.925C>A p.Q309K | Missense Mutation (SNP) | VAF 12/137 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.935); called by muse, mutect2
- ZNF804A | c.3091G>T p.E1031* | Nonsense Mutation (SNP) | VAF 17/126 reads (13%) | called by muse, mutect2, varscan2
- ABCC1 | c.1089C>T p.G363= | Silent (SNP) | VAF 7/109 reads (6%) | called by muse, mutect2
- ADAMTS5 | c.1539C>A p.V513= | Silent (SNP) | VAF 24/288 reads (8%) | called by muse, mutect2
- CSMD3 | c.6126T>A p.L2042= (on ENST00000297405 / NM_001363185.1; = p.L1938= on NM_052900.3) | Silent (SNP) | VAF 16/166 reads (10%) | called by muse, mutect2, varscan2
- DDHD1 | c.489T>C p.Y163= (on ENST00000323669; = p.Y360= on NM_030637.3) | Silent (SNP) | VAF 16/214 reads (7%) | catalogued as rs749268024; called by muse, mutect2
- EMD | c.675C>A p.L225= | Silent (SNP) | VAF 3/20 reads (15%) | called by muse, mutect2
- ESRRB | c.348C>A p.G116= | Silent (SNP) | VAF 3/23 reads (13%) | called by muse, mutect2
- HCLS1 | c.252A>T p.G84= | Silent (SNP) | VAF 13/137 reads (9%) | called by muse, mutect2, varscan2
- HOXB1 | c.759C>T p.N253= | Silent (SNP) | VAF 3/24 reads (13%) | called by muse, mutect2
- HYDIN | c.5766G>A p.L1922= | Silent (SNP) | VAF 19/167 reads (11%) | called by muse, mutect2, varscan2
- IGFBP1 | c.141G>T p.S47= | Silent (SNP) | VAF 9/77 reads (12%) | catalogued as COSV51875526; called by muse, mutect2, varscan2
- MKI67 | c.3141G>T p.T1047= | Silent (SNP) | VAF 16/131 reads (12%) | called by muse, mutect2, varscan2
- NKX2-1 | c.258C>T p.Y86= | Silent (SNP) | VAF 12/81 reads (15%) | catalogued as rs1292946504; called by muse, mutect2, varscan2
- NOTCH1 | c.2916C>T p.P972= | Silent (SNP) | VAF 15/137 reads (11%) | catalogued as rs754724517; ClinVar: likely benign; called by muse, mutect2, varscan2
- PCBP2 | c.477C>T p.V159= | Silent (SNP) | VAF 9/172 reads (5%) | called by muse, mutect2
- POF1B | c.1593A>T p.I531= | Silent (SNP) | VAF 13/238 reads (5%) | called by muse, mutect2
- PTK7 | c.1926C>T p.H642= | Silent (SNP) | VAF 3/39 reads (8%) | catalogued as rs1210889322; called by muse, mutect2
- TIMD4 | c.519C>A p.T173= | Silent (SNP) | VAF 24/330 reads (7%) | called by muse, mutect2
- TTC6 | c.2325G>C p.V775= | Silent (SNP) | VAF 7/42 reads (17%) | called by muse, varscan2
- VARS2 | c.646A>C p.R216= | Silent (SNP) | VAF 3/24 reads (13%) | called by muse, mutect2
- ZIC1 | c.1281C>T p.S427= | Silent (SNP) | VAF 16/126 reads (13%) | catalogued as rs1200372716, COSV51556115; ClinVar: likely benign; called by muse, mutect2, varscan2
- ZNF860 | c.861G>A p.K287= | Silent (SNP) | VAF 18/218 reads (8%) | called by muse, mutect2
- AP001267.5 | c.-799+33219C>T | Intron (SNP) | VAF 8/228 reads (4%) | called by muse, mutect2
- GOLGA3 | c.3267+14A>G | Intron (SNP) | VAF 10/122 reads (8%) | catalogued as rs888843397; called by muse, mutect2
- LILRB1 | c.1800+355C>A | Intron (SNP) | VAF 10/73 reads (14%) | called by muse, mutect2, varscan2
- PTPN6 | c.9-36G>T | Intron (SNP) | VAF 9/83 reads (11%) | called by muse, mutect2, varscan2
- SMOC2 | c.1323+666T>C | Intron (SNP) | VAF 14/150 reads (9%) | catalogued as rs768681567; called by muse, mutect2
- STIM2 | c.-177C>A | 5'UTR (SNP) | VAF 3/35 reads (9%) | called by muse, mutect2
- TAT | c.236-45del | Intron (DEL) | VAF 22/185 reads (12%) | called by mutect2, varscan2
- TNFAIP8 | c.-44A>G | 5'UTR (SNP) | VAF 9/114 reads (8%) | called by muse, mutect2
- TRIM39 | c.1010-303A>C | Intron (SNP) | VAF 4/72 reads (6%) | called by muse, mutect2
- TTN | c.4815-37C>G | Intron (SNP) | VAF 8/155 reads (5%) | called by muse, mutect2
- TTN | c.4815-38C>A | Intron (SNP) | VAF 10/156 reads (6%) | catalogued as COSV100630261; called by muse, mutect2
- XDH | c.*40G>T | 3'UTR (SNP) | VAF 7/160 reads (4%) | called by muse, mutect2
